Surgical pathology report (de-identified scan), TCGA case TCGA-CJ-6030, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CJ-6030-01A (Primary Tumor).

Department of Pathology

Tissue Source Site (TSS) #: [REDACTED]

Pathology Report

DIAGNOSIS

(A) LEFT KIDNEY, ADRENAL, AND LYMPH NODES:

RENAL CELL CARCINOMA (3.5 CM MAXIMUM DIMENSION), CONVENTIONAL TYPE
(75% CLEAR CELLS, 25%
EOSINOPHILIC CELLS), FUHRMAN NUCLEAR GRADE 3. (SEE COMMENT)

Margins of resection free of tumor.

Eleven lymph nodes, no tumor present.

Adrenal gland with cortical nodules, no metastatic renal cell carcinoma present.

COMMENT

The renal cell carcinoma in the left kidney is located near the hilum of the kidney and pushes into the renal sinus. Although there is no invasion into the renal sinus adipose tissue, there is invasion by tumor into a medium sized blood vessel within the renal sinus. There is no invasion into the perinephric adipose tissue or the renal vein.

GROSS DESCRIPTION

(A) LEFT KIDNEY AND ADRENAL - A left radical nephrectomy specimen (28.0 x 14.0 x 7.0 cm), including the kidney (14.0 x 6.0 x 5.0 cm), segment of ureter (13.0 cm in length x 0.3 cm in diameter), adrenal gland (5.5 x 2.0 x 1.0 cm), and segment of renal vein (2.0 cm in length x 0.8 cm in diameter).

There is a hemorrhagic solid and cystic yellow mass (3.5 x 3.0 x 3.0 cm) in the renal hilum which bulges into and distorts the pelvicalyceal system and renal sinus. However, gross invasion into the renal sinus adipose tissue and renal collecting system is not seen. There is no invasion of the renal vein or the perinephric adipose tissue.

The adrenal gland is focally nodular. However, there are no other lesions or masses.

Multiple soft unremarkable lymph nodes are identified and are submitted in their entirety as described below in the Section Code.

INK CODE: Black-Gerota's fascia nearest tumor.

SECTION CODE: A1, representative section of tumor for frozen section; A2, renal vein margin; A3, vascular and ureter margin; A4, representative section of non-neoplastic kidney; A5, A6, representative sections of adrenal gland; A7-A14, representative sections of tumor; A15, tumor with Gerota's fascia margin; A16-A19, one lymph node serially sectioned; A20-A22, one lymph node serially sectioned; A23, one bisected lymph node; A24, one bisected lymph node; A25-A27, multiple lymph nodes.

*FS/DX: RENAL CELL CARCINOMA. [REDACTED]

CLINICAL HISTORY

None given.

SNOMED CODES

T-71000, M-83123

Source: NCI Genomic Data Commons file c7d19208-23f9-42e9-8881-294e0002c7df (TCGA-CJ-6030.739FE9CD-EB85-4B49-897A-546FD12E895C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).